Somatic mutation profile of tumor specimen ALCH-B28H-TTR1-A (aliquot ALCH-B28H-TTR1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B28H, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 66.8 years (24,383 days).
Specimen ALCH-B28H-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0613f07-ba9f-4f0d-8dbb-7654697dcc64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B28H-NB1-A (Blood Derived Normal), aliquot ALCH-B28H-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca659d1b-8067-4d38-b029-c4dae242d5c0

The open-access MAF lists 655 somatic variants for this specimen: 219 protein-altering or splice-affecting, 354 silent, 82 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 354, Missense Mutation 184, Intron 45, 5'UTR 19, Nonsense Mutation 18, RNA 10, Frame Shift Del 6, Splice Region 3, Splice Site 3, Frame Shift Ins 3, 3'UTR 3, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OTC | c.418G>C p.A140P | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72556260, CM930525, COSV99234415; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PRKCG | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121918511, CM031334; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 8/26 reads (31%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.4075G>A p.E1359K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV60623808; called by mutect2, varscan2
- ABCC2 | c.572C>G p.S191* | Nonsense Mutation (SNP) | VAF 16/222 reads (7%) | catalogued as COSV64970651; called by muse, mutect2
- AC063943.2 | c.196T>C p.F66L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); catalogued as COSV58044014; called by muse, varscan2
- ADGRV1 | c.10316G>T p.G3439V | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as rs760608174; called by muse, mutect2, varscan2
- AGA | c.961T>A p.S321T | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.036); catalogued as COSV99219395; called by muse, mutect2, varscan2
- AK5 | c.983G>A p.G328D (on ENST00000354567 / NM_174858.3; = p.G302D on NM_012093.4) | Missense Mutation (SNP) | VAF 40/286 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs767465345; called by muse, mutect2, varscan2
- ANKRD30B | c.2497G>A p.A833T | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV57703857; called by muse, mutect2
- ANKUB1 | c.873A>T p.L291F | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs762463717; called by muse, mutect2, varscan2
- APOB | c.5956C>T p.Q1986* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV51951185; called by muse, mutect2, varscan2
- ARHGEF10 | c.1695G>C p.Q565H (on ENST00000398564; = p.Q540H on NM_014629.4) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs967302729; called by muse, mutect2, varscan2
- ARMC12 | c.196G>T p.D66Y (on ENST00000373866 / NM_001286574.2; = p.D93Y on NM_145028.5) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55359951, COSV99849347; called by muse, mutect2, varscan2
- ASAP2 | c.44A>T p.H15L | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs1251177142; called by muse, mutect2
- ATP10B | c.1468G>T p.A490S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.012); catalogued as COSV58780901; called by muse, mutect2, varscan2
- ATP13A2 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV58701156, COSV58704128; called by mutect2, varscan2
- BCHE | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1301323421; called by muse, mutect2, varscan2
- BNC2 | c.165G>C p.E55D | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66140571; called by muse, varscan2
- C1orf105 | c.319T>C p.F107L | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.495); catalogued as COSV62959363; called by muse, mutect2, varscan2
- C1orf167 | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.18); catalogued as rs753637610, COSV57174013; called by mutect2, varscan2
- C5orf34 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs1023917002, COSV60932250; called by muse, mutect2
- CACNA1D | c.5154T>G p.I1718M (on ENST00000350061 / NM_001128840.3; = p.I1738M on NM_000720.4) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.057); catalogued as COSV55437088; called by muse, mutect2, varscan2
- CCDC110 | c.671A>T p.K224I | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as COSV104409874; called by muse, mutect2
- CELSR2 | c.8278G>A p.G2760S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.006); catalogued as rs763861765; called by mutect2, varscan2
- COL22A1 | c.3956C>T p.P1319L | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as rs1247165542, COSV57341381; called by muse, mutect2, varscan2
- COL6A6 | c.4336G>T p.G1446C | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100649670; called by muse, mutect2, varscan2
- COL9A1 | c.366C>G p.S122R | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as COSV61829552; called by muse, mutect2, varscan2
- CSMD1 | c.10258G>T p.G3420C (on ENST00000520002; = p.G3419C on NM_033225.6) | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100152443; called by muse, mutect2, varscan2
- CSMD1 | c.6151C>T p.P2051S (on ENST00000520002; = p.P2050S on NM_033225.6) | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753451258; called by muse, mutect2, varscan2
- CSMD3 | c.6229C>T p.Q2077* (on ENST00000297405 / NM_001363185.1; = p.Q1973* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 31/456 reads (7%) | catalogued as COSV52165547, COSV52353929; called by muse, mutect2
- CSMD3 | c.2513G>A p.G838E (on ENST00000297405 / NM_001363185.1; = p.G734E on NM_052900.3) | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52250069; called by muse, mutect2, varscan2
- CYSLTR1 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs758713318; called by muse, mutect2, varscan2
- DDX18 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99604838; called by muse, mutect2, varscan2
- DISP3 | c.2635A>G p.N879D | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV53829349; called by muse, mutect2
- EWSR1 | c.880A>T p.M294L | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV58421268; called by muse, mutect2
- FAM135B | c.2549G>A p.G850E | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.058); catalogued as rs370460671, COSV52731262; called by muse, mutect2, varscan2
- FOXG1 | c.1289G>C p.S430T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.259); catalogued as COSV57394828, COSV57395595; called by muse, varscan2
- FREM2 | c.3748G>A p.E1250K | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs1000912828, COSV54829636; called by muse, mutect2, varscan2
- GPR158 | c.3470C>A p.S1157* | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | catalogued as COSV100893130; called by mutect2, varscan2
- GTF3C4 | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs769535681; called by mutect2, varscan2
- HFM1 | c.1463C>A p.P488Q | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1431103308; called by muse, mutect2, varscan2
- HOXC5 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs763873244, COSV54536233; called by muse, varscan2
- IER5L | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1477396220; called by muse, mutect2
- JAG2 | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1285754373, COSV59306364; called by muse, varscan2
- JAG2 | c.191A>G p.H64R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1364331833, COSV59306384; called by muse, varscan2
- KEAP1 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs145222481, CX135162, COSV50286368; called by mutect2, varscan2
- KRTAP10-2 | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV59951594; called by muse, varscan2
- MBD5 | c.1120G>A p.V374I | Missense Mutation (SNP) | VAF 26/544 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV68695519; called by muse, mutect2
- MDGA2 | c.217C>G p.L73V | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV67792380; called by muse, mutect2
- MED13 | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1359232664, COSV67264033; called by muse, mutect2
- MEIS2 | c.1315A>G p.M439V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV54930798, COSV54945955; called by muse, mutect2, varscan2
- MGA | c.4204T>A p.C1402S | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV54948532; called by muse, varscan2
- MGA | c.4281G>T p.E1427D | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV54948548; called by muse, varscan2
- MYH9 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 54/259 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53383943; called by muse, mutect2, varscan2
- NAV3 | c.1320del p.V442Cfs*50 | Frame Shift Del (DEL) | VAF 19/132 reads (14%) | catalogued as COSV57064769; called by mutect2, pindel, varscan2
- NDUFA12 | c.422C>G p.S141* | Nonsense Mutation (SNP) | VAF 12/236 reads (5%) | catalogued as COSV100580900; called by muse, mutect2
- NLRP12 | c.1122C>A p.F374L | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs766035651; called by muse, mutect2, varscan2
- NLRP12 | c.863del p.R288Pfs*40 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as COSV60743363; called by mutect2, pindel, varscan2
- NR1D1 | c.1739T>C p.L580S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV52840542; called by muse, mutect2, varscan2
- NRN1 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1206195664; called by muse, varscan2
- OBI1 | c.1010A>T p.N337I | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as rs774614872; called by mutect2, varscan2
- OR4K1 | c.446G>T p.W149L | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53461119, COSV53462369; called by muse, mutect2, varscan2
- OR5K2 | c.548C>A p.P183H | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71143203; called by muse, mutect2, varscan2
- OR6F1 | c.287G>T p.S96I | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV100128933; called by muse, mutect2, varscan2
- PEX12 | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs988442642, COSV56777592; called by muse, mutect2
- PHF14 | c.2141G>T p.G714V | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); catalogued as rs1384407575; called by muse, mutect2
- PKHD1 | c.6020G>T p.G2007V | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as CM149118; called by muse, mutect2, varscan2
- PLCD3 | c.782A>G p.H261R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs1160131157; called by mutect2, varscan2
- PLG | c.1531C>T p.H511Y | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99804527; called by muse, mutect2
- RASA3 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs1200479395; called by muse, varscan2
- RETREG2 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs767340482, COSV56086892; called by muse, varscan2
- RNF38 | c.37T>C p.S13P | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52392820; called by muse, varscan2
- RUNDC3B | c.500A>G p.K167R | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs866004904; called by muse, mutect2, varscan2
- RUNX2 | c.59-5C>T | Splice Region (SNP) | VAF 11/76 reads (14%) | catalogued as rs927950471; called by muse, mutect2, varscan2
- SALL4 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.84); catalogued as rs772877973; called by muse, mutect2, varscan2
- SFMBT2 | c.359G>C p.W120S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62817226; called by muse, mutect2, varscan2
- SOX10 | c.216C>G p.I72M | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61005041; called by muse, varscan2
- STXBP5L | c.2093A>G p.N698S | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs774030165; called by muse, mutect2, varscan2
- SYNCRIP | c.1723T>A p.S575T | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.827); catalogued as COSV62286403; called by muse, varscan2
- SYNE1 | c.7009G>A p.E2337K (on ENST00000367255 / NM_182961.4; = p.E2344K on NM_033071.3) | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs1385505345; called by muse, mutect2
- THRA | c.1363G>T p.A455S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.068); catalogued as COSV52840565; called by muse, mutect2, varscan2
- TRIM2 | c.1582C>G p.R528G (on ENST00000437508; = p.R555G on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58635738; called by muse, mutect2, varscan2
- TRIM2 | c.1583G>C p.R528P (on ENST00000437508; = p.R555P on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58632353; called by mutect2, varscan2
- TSKU | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs374470717; called by muse, mutect2
- TSPAN2 | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 19/131 reads (15%) | catalogued as COSV65690485; called by muse, mutect2, varscan2
- TTC3 | c.929C>G p.S310C | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV61285660; called by muse, mutect2
- USP34 | c.3989G>T p.C1330F | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.962); catalogued as rs1279734522, COSV68401873; called by muse, mutect2, varscan2
- VWA3B | c.121C>T p.Q41* | Nonsense Mutation (SNP) | VAF 16/212 reads (8%) | catalogued as rs1486260168; called by muse, mutect2
- WDR20 | c.83C>A p.P28Q | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV54470232; called by muse, varscan2
- XKR6 | c.160A>C p.M54L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs1175561772; called by muse, varscan2
- ZIC1 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.902); catalogued as rs772678194, COSV99292295; called by mutect2, varscan2
- ZIC5 | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.006); catalogued as COSV57437894; called by muse, mutect2, varscan2
- ZMIZ1 | c.2914T>G p.S972A | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.015); catalogued as rs1287450241; called by muse, varscan2
- ZMYM4 | c.2405G>A p.C802Y | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58909854; called by muse, mutect2
- ZNF280A | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV57480163, COSV57481635; called by muse, mutect2, varscan2
- ZNF311 | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369718686; called by muse, mutect2, varscan2
- ZNF326 | c.302G>C p.S101T | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV61034132; called by muse, varscan2
- ZNF679 | c.1211del p.G404Efs*19 | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | catalogued as COSV55378362; called by mutect2, varscan2
- ZNF737 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 16/215 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs371460168, COSV101417642; called by muse, mutect2
- ZNF880 | c.1343G>A p.R448K | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs879077292; called by muse, mutect2, varscan2
- ACCS | c.833G>A p.R278K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.679); called by mutect2, varscan2
- ADAM2 | c.811T>A p.Y271N | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGB | c.4930G>T p.A1644S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- ADGRG4 | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- ADPRHL1 | c.662G>A p.W221* | Nonsense Mutation (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- ADRA1B | c.64A>G p.N22D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); called by muse, varscan2
- ADRA1B | c.124A>G p.I42V | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, varscan2
- AHNAK | c.11492C>T p.A3831V | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.939); called by muse, varscan2
- AMD1 | c.119G>C p.W40S | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARL5A | c.492-1G>T p.X164_splice | Splice Site (SNP) | VAF 40/285 reads (14%) | called by muse, mutect2, varscan2
- ATP13A3 | c.3101A>T p.Y1034F | Missense Mutation (SNP) | VAF 90/524 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- BRINP3 | c.1053T>A p.F351L | Missense Mutation (SNP) | VAF 38/274 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, varscan2
- BRSK1 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- BRWD3 | c.3830A>T p.D1277V | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- C5orf34 | c.1160A>T p.E387V | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- C5orf51 | c.401G>A p.R134K | Missense Mutation (SNP) | VAF 60/458 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- C9orf43 | c.325T>G p.C109G | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CADPS2 | c.926T>A p.L309* | Nonsense Mutation (SNP) | VAF 43/187 reads (23%) | called by muse, mutect2, varscan2
- CBY2 | c.571A>T p.K191* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | called by mutect2, varscan2
- CCDC85A | c.1381T>C p.S461P | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); called by muse, varscan2
- CCNA2 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CELF4 | c.1270T>C p.F424L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); called by muse, mutect2
- CILK1 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.633T>A p.D211E | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CTNNA3 | c.1724C>A p.T575K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.82); called by mutect2, varscan2
- CTNND2 | c.220C>A p.Q74K | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2
- CYB561D1 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- DCAF8L1 | c.1160G>T p.C387F | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.096); called by muse, mutect2
- DCC | c.3479T>C p.M1160T | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- DGKK | c.1542A>T p.Q514H | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- DLEC1 | c.2020G>T p.D674Y | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNALI1 | c.811C>T p.Q271* (on ENST00000296218; = p.Q249* on NM_003462.5) | Nonsense Mutation (SNP) | VAF 41/281 reads (15%) | called by muse, mutect2, varscan2
- DOCK10 | c.244-2A>G p.X82_splice | Splice Site (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2, varscan2
- DPRX | c.110A>G p.E37G | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- EIF2S3 | c.1141C>T p.L381F | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ENPP4 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 18/285 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- EPHA6 | c.1388G>C p.C463S | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- F11 | c.1828A>G p.N610D | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2
- FAM135A | c.4291C>T p.H1431Y (on ENST00000370479 / NM_001351599.1; = p.H1218Y on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FCRL1 | c.494C>G p.T165R | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FHL1 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- FPR3 | c.992C>G p.S331* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- GLI3 | c.1178T>C p.I393T | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.024); called by muse, varscan2
- GNAT3 | c.590+1G>A p.X197_splice | Splice Site (SNP) | VAF 46/182 reads (25%) | called by muse, mutect2, varscan2
- GRIK1 | c.1606T>A p.Y536N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- HMCN1 | c.14042A>G p.Y4681C | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.529); called by muse, mutect2
- HNRNPA1 | c.879_881dup p.G297dup | In Frame Ins (INS) | VAF 10/90 reads (11%) | called by pindel, varscan2
- HTATSF1 | c.2200G>C p.E734Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.518); called by muse, mutect2
- IFFO1 | c.1223A>G p.N408S (on ENST00000396840 / NM_001330324.2; = p.N411S on NM_080730.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, varscan2
- IFI44 | c.774del p.E259Kfs*13 | Frame Shift Del (DEL) | VAF 26/199 reads (13%) | called by mutect2, pindel, varscan2
- KCMF1 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); called by muse, mutect2
- KRTAP15-1 | c.292G>T p.G98* | Nonsense Mutation (SNP) | VAF 26/102 reads (25%) | called by muse, mutect2, varscan2
- LMX1A | c.128T>C p.L43S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, varscan2
- LRRIQ3 | c.483T>G p.D161E | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAGEB18 | c.866C>A p.A289D | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP7 | c.11T>A p.L4Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, varscan2
- MAST2 | c.3301A>T p.M1101L | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- MBD1 | c.1093A>G p.S365G (on ENST00000269468 / NM_001323950.1; = p.S342G on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, varscan2
- MDGA2 | c.1753C>G p.Q585E (on ENST00000399232 / NM_001113498.2; = p.Q287E on NM_182830.4) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); called by muse, varscan2
- MED12L | c.1447C>A p.L483I | Missense Mutation (SNP) | VAF 25/287 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- MEF2C | c.1233_1235dup p.T412dup | In Frame Ins (INS) | VAF 8/75 reads (11%) | called by pindel, varscan2
- MGAT2 | c.936G>T p.W312C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); called by muse, varscan2
- MMP26 | c.338A>T p.H113L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.026); called by muse, mutect2
- MRFAP1 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | called by muse, varscan2
- MRPL39 | c.861A>T p.Q287H | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MSN | c.337G>C p.D113H | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MYO1D | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- N4BP2 | c.2114T>G p.M705R | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- N4BP2L2 | c.2192G>A p.R731K (on ENST00000674422; = p.R302K on NM_033111.4) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NAA25 | c.2872dup p.E958Gfs*8 | Frame Shift Ins (INS) | VAF 46/362 reads (13%) | called by mutect2, pindel, varscan2
- NOBOX | c.583G>T p.G195* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- OAZ2 | c.64dup p.R22Kfs*38 | Frame Shift Ins (INS) | VAF 6/40 reads (15%) | called by pindel, varscan2
- OR5D14 | c.520A>G p.N174D | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- PAPPA | c.26A>G p.H9R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2
- PCDHGB7 | c.224T>A p.F75Y | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PDS5A | c.677A>G p.D226G | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PHF12 | c.1364A>C p.H455P | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- PHKA2 | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PIGK | c.150G>T p.V50= | Splice Region (SNP) | VAF 23/150 reads (15%) | called by muse, mutect2, varscan2
- PIK3CG | c.1491C>G p.F497L | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTPRD | c.5275C>A p.P1759T | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PTPRZ1 | c.896C>G p.S299* | Nonsense Mutation (SNP) | VAF 22/104 reads (21%) | called by muse, mutect2, varscan2
- PYROXD2 | c.1445G>A p.R482K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBBP5 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RBM6 | c.103dup p.L35Pfs*2 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by mutect2, pindel
- RGMA | c.90C>G p.F30L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ROBO2 | c.1927A>T p.N643Y | Missense Mutation (SNP) | VAF 45/240 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ROPN1L | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- RTKN | c.1314A>T p.K438N (on ENST00000272430 / NM_001015055.2; = p.K425N on NM_033046.2) | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SCN7A | c.4448C>T p.S1483L | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- SEC62 | c.660G>A p.M220I | Missense Mutation (SNP) | VAF 32/436 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.127); called by muse, mutect2
- SEMA5A | c.833G>T p.C278F | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SESTD1 | c.1763A>G p.K588R | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- SMARCA5 | c.1592G>A p.G531D | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SMC4 | c.1459G>T p.G487C | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- STAB2 | c.4577A>T p.K1526M | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.866); called by muse, mutect2
- STON1-GTF2A1L | c.2761A>G p.I921V | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX50 | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- TLN2 | c.7364G>A p.R2455K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TNC | c.4649T>C p.M1550T | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, varscan2
- TRAPPC10 | c.3092T>G p.F1031C | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRPM5 | c.3128T>A p.L1043Q | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TUBB4B | c.1259C>T p.S420F | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); called by muse, varscan2
- UBC | c.806A>T p.Q269L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- UGP2 | c.187C>A p.H63N | Missense Mutation (SNP) | VAF 22/422 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.216); called by muse, mutect2
- UQCRC2 | c.330A>C p.L110F | Missense Mutation (SNP) | VAF 22/241 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); called by muse, mutect2
- UROC1 | c.358del p.Q120Rfs*4 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | called by mutect2, pindel, varscan2
- USF3 | c.5563G>C p.E1855Q | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- USH2A | c.11063C>A p.P3688H | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- VAV3 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 13/209 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- VGLL3 | c.334C>T p.Q112* | Nonsense Mutation (SNP) | VAF 16/128 reads (13%) | called by muse, varscan2
- XIRP2 | c.5522T>C p.V1841A (on ENST00000628543; = p.V2016A on NM_152381.6) | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- YTHDC2 | c.1824G>C p.L608F | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- ZNF23 | c.1492C>T p.H498Y | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF534 | c.973A>T p.S325C (on ENST00000332323 / NM_001143939.3; = p.S312C on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ZNF749 | c.1613C>G p.S538* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- ZRANB2 | c.986del p.K329Rfs*10 | Frame Shift Del (DEL) | VAF 32/194 reads (16%) | called by mutect2, pindel, varscan2
- ZWINT | c.811G>C p.A271P | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- ABCG8 | c.885G>T p.G295= | Silent (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- AC004922.1 | c.1038C>T p.H346= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs767480160; called by muse, varscan2
- ACIN1 | c.222G>T p.A74= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV52977419; called by muse, mutect2
- ACLY | c.2334T>C p.A778= | Silent (SNP) | VAF 14/169 reads (8%) | called by muse, mutect2
- ACLY | c.1224G>A p.E408= | Silent (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2
- ACSS2 | c.1971C>A p.T657= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV53623465; called by muse, mutect2
- ACVR2B | c.78A>T p.T26= | Silent (SNP) | VAF 5/26 reads (19%) | called by mutect2, varscan2
- ADCY3 | c.225C>T p.H75= | Silent (SNP) | VAF 4/51 reads (8%) | called by muse, mutect2
- ADGRB1 | c.2745C>T p.D915= | Silent (SNP) | VAF 7/17 reads (41%) | called by muse, varscan2
- ADGRL2 | c.2391T>C p.T797= (on ENST00000370717 / NM_001366005.1; = p.T784= on NM_012302.4) | Silent (SNP) | VAF 10/250 reads (4%) | called by muse, mutect2
- AGAP1 | c.1398C>T p.D466= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs778878290, COSV58328926; called by muse, varscan2
- AMBRA1 | c.2085A>G p.E695= (on ENST00000458649 / NM_001367468.1; = p.E605= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1304721302; called by muse, varscan2
- AMD1 | c.261G>A p.L87= | Silent (SNP) | VAF 45/299 reads (15%) | catalogued as rs1284561715, COSV64386891; called by muse, mutect2
- AMD1 | c.402A>C p.I134= | Silent (SNP) | VAF 23/267 reads (9%) | called by muse, mutect2
- ANK1 | c.9A>G p.Q3= | Silent (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- ANK2 | c.3189T>C p.I1063= | Silent (SNP) | VAF 14/130 reads (11%) | catalogued as COSV52145060; called by muse, varscan2
- ANKRD13B | c.48T>C p.Y16= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs772034182, COSV56609931; called by muse, varscan2
- APH1A | c.513T>C p.H171= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV52529514; called by muse, varscan2
- ARF6 | c.399C>T p.H133= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as rs1386248214, COSV53597216; called by muse, varscan2
- ARFGEF2 | c.9G>A p.E3= | Silent (SNP) | VAF 8/24 reads (33%) | called by muse, varscan2
- ARGLU1 | c.303A>C p.R101= | Silent (SNP) | VAF 7/65 reads (11%) | called by mutect2, varscan2
- ARHGAP23 | c.2376C>T p.D792= | Silent (SNP) | VAF 10/59 reads (17%) | called by muse, varscan2
- ARHGAP26 | c.2250A>C p.V750= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2
- ARHGEF9 | c.90A>G p.K30= | Silent (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- ARID1B | c.720G>T p.A240= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV51665444; called by muse, mutect2
- ARL4C | c.282C>T p.D94= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs1456019667, COSV60213348; called by muse, mutect2
- ASIC4 | c.48G>A p.A16= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs768160285; called by mutect2, varscan2
- ASTN1 | c.1410C>T p.P470= | Silent (SNP) | VAF 8/27 reads (30%) | called by muse, varscan2
- ASTN1 | c.1368A>G p.G456= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV56072160; called by muse, varscan2
- ATP6V0D2 | c.762G>T p.L254= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs765480746, COSV53418710; called by mutect2, varscan2
- ATXN1L | c.1218T>C p.H406= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs1331042845; called by muse, mutect2
- BCL11A | c.954G>A p.P318= (on ENST00000335712 / NM_001365609.1; = p.P352= on NM_018014.4) | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV59624023; called by muse, varscan2
- BCL11B | c.2499C>T p.C833= (on ENST00000357195 / NM_001282237.2; = p.C762= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs749985774; called by muse, mutect2, varscan2
- BCL11B | c.1344T>C p.S448= (on ENST00000357195 / NM_001282237.2; = p.S377= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs764547816, COSV61736232; called by muse, mutect2
- BCL2 | c.552C>T p.H184= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs563883873; called by muse, varscan2
- BIRC6 | c.4893A>G p.L1631= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV70195417, COSV70207251; called by muse, mutect2, varscan2
- BIRC6 | c.7956C>G p.V2652= | Silent (SNP) | VAF 19/131 reads (15%) | catalogued as rs1425074593, COSV101428485; called by muse, mutect2, varscan2
- BRINP1 | c.186T>G p.R62= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as COSV56291629; called by muse, varscan2
- BST1 | c.819C>T p.D273= | Silent (SNP) | VAF 19/138 reads (14%) | called by muse, mutect2, varscan2
- C12orf66 | c.99T>C p.A33= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV61323524; called by muse, varscan2
- C16orf87 | c.45A>G p.S15= | Silent (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- CACNG2 | c.591G>C p.A197= | Silent (SNP) | VAF 16/90 reads (18%) | called by muse, varscan2
- CALCRL | c.693C>T p.L231= | Silent (SNP) | VAF 18/262 reads (7%) | called by muse, mutect2
- CAMK2A | c.834A>C p.A278= | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, varscan2
- CAPZA1 | c.828C>T p.S276= | Silent (SNP) | VAF 22/188 reads (12%) | called by muse, mutect2
- CASZ1 | c.4521C>G p.P1507= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV65461036; called by muse, mutect2
- CASZ1 | c.1911C>T p.D637= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs151000185; called by mutect2, varscan2
- CBLL1 | c.825A>T p.R275= | Silent (SNP) | VAF 10/152 reads (7%) | catalogued as COSV56028111; called by muse, mutect2
- CCDC85C | c.165C>T p.D55= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1296748075; called by muse, varscan2
- CDK12 | c.3810C>T p.P1270= (on ENST00000447079 / NM_016507.4; = p.P1261= on NM_015083.3) | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs748058337, COSV70999206, COSV70999671, COSV71002382; called by muse, varscan2
- CDK5R2 | c.840A>G p.P280= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs760088475; called by muse, varscan2
- CDK5R2 | c.930G>A p.R310= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs1192336701; called by muse, varscan2
- CEACAM5 | c.1116C>A p.S372= | Silent (SNP) | VAF 35/191 reads (18%) | called by muse, mutect2, varscan2
- CELF1 | c.781T>C p.L261= (on ENST00000358597 / NM_001376422.1; = p.L257= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 8/36 reads (22%) | called by muse, varscan2
- CELF4 | c.1401C>A p.I467= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1420001251, COSV58446037; called by muse, varscan2
- CHTF8 | c.96T>C p.T32= | Silent (SNP) | VAF 10/62 reads (16%) | called by muse, varscan2
- CITED2 | c.54T>C p.N18= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV62726318; called by muse, varscan2
- CLASP1 | c.2232T>C p.P744= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- CLK3 | c.870T>C p.G290= (on ENST00000395066 / NM_001130028.1; = p.G142= on NM_003992.4) | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs1323690218, COSV61411668; called by muse, mutect2, varscan2
- CLK3 | c.1194T>C p.N398= (on ENST00000395066 / NM_001130028.1; = p.N250= on NM_003992.4) | Silent (SNP) | VAF 9/80 reads (11%) | called by muse, varscan2
- CNOT1 | c.6366A>T p.P2122= | Silent (SNP) | VAF 15/212 reads (7%) | catalogued as COSV55312762; called by muse, mutect2
- CNOT2 | c.1332C>T p.L444= | Silent (SNP) | VAF 19/275 reads (7%) | called by muse, mutect2
- CR1 | c.5694C>T p.S1898= | Silent (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- CTDNEP1 | c.72C>T p.F24= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs780212973; called by muse, mutect2, varscan2
- CXXC4 | c.900A>G p.P300= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs377103900; called by muse, varscan2
- CXXC4 | c.876A>G p.S292= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV67295669; called by muse, varscan2
- CXXC4 | c.696C>G p.R232= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV67295676; called by muse, varscan2
- CYP21A2 | c.609C>T p.S203= | Silent (SNP) | VAF 13/131 reads (10%) | called by muse, mutect2, varscan2
- DAB2IP | c.285G>A p.K95= (on ENST00000408936; = p.K67= on NM_032552.3) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1306261279; called by muse, varscan2
- DAB2IP | c.336C>A p.A112= (on ENST00000408936; = p.A84= on NM_032552.3) | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs1430588502; called by muse, varscan2
- DDX5 | c.1383T>G p.R461= | Silent (SNP) | VAF 16/277 reads (6%) | catalogued as COSV56747267; called by muse, mutect2
- DDX59 | c.1410G>A p.L470= | Silent (SNP) | VAF 10/129 reads (8%) | called by muse, mutect2
- DES | c.339G>A p.Q113= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs1209658312; called by muse, mutect2
- DGCR8 | c.294C>T p.T98= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs374194876; called by muse, mutect2, varscan2
- DGKD | c.3501A>G p.T1167= (on ENST00000264057 / NM_152879.3; = p.T1123= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- DLGAP3 | c.81T>A p.P27= | Silent (SNP) | VAF 9/32 reads (28%) | called by muse, varscan2
- DTX3L | c.1113C>G p.A371= | Silent (SNP) | VAF 56/208 reads (27%) | catalogued as COSV99950085; called by muse, mutect2, varscan2
- DYNLL2 | c.180A>G p.R60= | Silent (SNP) | VAF 11/191 reads (6%) | catalogued as COSV74093366; called by muse, mutect2
- DYRK1B | c.1110C>T p.P370= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs1383348111; called by muse, varscan2
- EDRF1 | c.2625G>A p.L875= (on ENST00000356792 / NM_001202438.2; = p.L841= on NM_015608.2) | Silent (SNP) | VAF 15/204 reads (7%) | called by muse, mutect2
- EFHD2 | c.285G>A p.K95= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV65658208; called by muse, varscan2
- EHD4 | c.1497T>A p.L499= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV55005299; called by muse, mutect2, varscan2
- EIF4E2 | c.723G>A p.R241= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, varscan2
- EIF5A | c.87C>T p.G29= | Silent (SNP) | VAF 22/150 reads (15%) | called by muse, varscan2
- ELAVL4 | c.675C>G p.L225= | Silent (SNP) | VAF 10/98 reads (10%) | called by muse, varscan2
- ELOA | c.18C>T p.S6= | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, varscan2
- EMID1 | c.1137G>A p.Q379= | Silent (SNP) | VAF 9/92 reads (10%) | called by muse, mutect2
- EXD2 | c.1776C>T p.P592= (on ENST00000312994 / NM_001193362.1; = p.P467= on NM_018199.3) | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- EXOC4 | c.33A>G p.R11= | Silent (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- FADS3 | c.132C>T p.R44= | Silent (SNP) | VAF 7/27 reads (26%) | called by muse, varscan2
- FAM102B | c.75T>C p.N25= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as rs1302554675, COSV64240178; called by muse, varscan2
- FAM222B | c.891C>T p.P297= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV57927626; called by muse, varscan2
- FAM43A | c.69C>T p.P23= | Silent (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2
- FAM47A | c.1803T>C p.Y601= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV104414104; called by muse, mutect2, varscan2
- FBXL14 | c.270C>G p.A90= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV59335896; called by muse, varscan2
- FBXL20 | c.576G>A p.R192= | Silent (SNP) | VAF 17/273 reads (6%) | catalogued as rs1397383183, COSV99233676; called by muse, mutect2
- FEZF1 | c.1152T>G p.V384= | Silent (SNP) | VAF 14/284 reads (5%) | called by muse, mutect2
- FGF12 | c.123C>T p.C41= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs753826180; called by muse, varscan2
- FGF17 | c.126C>T p.A42= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, varscan2
- FOXA2 | c.558C>T p.Y186= (on ENST00000377115 / NM_153675.3; = p.Y192= on NM_021784.5) | Silent (SNP) | VAF 14/80 reads (18%) | called by muse, varscan2
- FOXB2 | c.162A>G p.T54= | Silent (SNP) | VAF 4/23 reads (17%) | called by muse, varscan2
- FOXD3 | c.657G>C p.P219= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV64379719, COSV64380138; called by muse, varscan2
- FOXG1 | c.987C>G p.G329= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV57395015; called by muse, varscan2
- FOXG1 | c.1191T>C p.S397= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs1315297792, COSV57395065; called by muse, varscan2
- FOXP2 | c.1386A>T p.S462= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as COSV63482116; called by muse, varscan2
- FOXQ1 | c.603G>A p.E201= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs1427650688; called by muse, varscan2
- FRMD4B | c.99G>C p.T33= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1355829241; called by muse, varscan2
- FRMD5 | c.36C>T p.S12= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV68723142; called by muse, varscan2
- FRMPD3 | c.5262A>G p.Q1754= | Silent (SNP) | VAF 40/258 reads (16%) | catalogued as rs1201202558; called by muse, varscan2
- FRMPD3 | c.5310G>A p.Q1770= | Silent (SNP) | VAF 64/247 reads (26%) | catalogued as rs1405680572, COSV52196669; called by muse, varscan2
- GALNT13 | c.1002G>A p.E334= | Silent (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- GATAD2B | c.1317T>C p.I439= | Silent (SNP) | VAF 12/302 reads (4%) | called by muse, mutect2
- GBX2 | c.57C>T p.S19= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs770456366, COSV60445481; called by mutect2, varscan2
- GDAP1L1 | c.876T>C p.D292= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV61156027; called by mutect2, varscan2
- GGNBP2 | c.66T>C p.I22= | Silent (SNP) | VAF 6/29 reads (21%) | called by muse, varscan2
- GID4 | c.361C>T p.L121= | Silent (SNP) | VAF 5/11 reads (45%) | called by muse, varscan2
- GNA13 | c.219G>C p.G73= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV71474384, COSV71474868; called by muse, varscan2
- GNAO1 | c.12T>G p.T4= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV52615340; called by muse, varscan2
- GNAS | c.60T>C p.R20= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs1391764576; called by muse, varscan2
- GNG5 | c.156A>G p.V52= | Silent (SNP) | VAF 22/310 reads (7%) | catalogued as COSV55364658; called by muse, mutect2
- GOLPH3 | c.195A>G p.E65= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as rs750300782; called by mutect2, varscan2
- GPR27 | c.645G>A p.R215= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1325267630; called by muse, varscan2
- GRIA2 | c.1728G>A p.E576= | Silent (SNP) | VAF 12/238 reads (5%) | catalogued as COSV52380962; called by muse, mutect2
- GRIA4 | c.2529A>G p.E843= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as COSV56879830, COSV99231698; called by muse, mutect2
- GRM7 | c.2595G>C p.A865= | Silent (SNP) | VAF 24/170 reads (14%) | called by muse, varscan2
- GUCY1A2 | c.468G>A p.Q156= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV99972079, COSV99972106; called by muse, mutect2, varscan2
- HCN4 | c.45C>T p.L15= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs1331595223; called by muse, varscan2
- HDAC5 | c.3051T>C p.A1017= | Silent (SNP) | VAF 3/19 reads (16%) | called by muse, varscan2
- HERPUD2 | c.33C>T p.T11= | Silent (SNP) | VAF 11/115 reads (10%) | catalogued as COSV60945601; called by muse, mutect2, varscan2
- HES5 | c.195T>C p.A65= | Silent (SNP) | VAF 7/27 reads (26%) | called by muse, varscan2
- HNRNPAB | c.864T>G p.P288= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV57422728; called by muse, varscan2
- HNRNPF | c.381T>C p.I127= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs1186871372, COSV61561150; called by muse, mutect2
- HNRNPR | c.1863G>A p.Q621= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV56419663; called by muse, mutect2
- HOXA11 | c.100C>T p.L34= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV50052775; called by muse, mutect2, varscan2
- HOXB5 | c.159C>T p.D53= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV53312084; called by muse, mutect2
- HOXB9 | c.375T>G p.P125= | Silent (SNP) | VAF 4/17 reads (24%) | called by muse, varscan2
- HOXC4 | c.624C>T p.R208= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs755113408, COSV57697819; called by muse, varscan2
- HOXC5 | c.288C>T p.P96= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs1053908057, COSV54536093; called by muse, varscan2
- HOXD10 | c.169C>T p.L57= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV50897982; called by muse, varscan2
- HOXD10 | c.573C>G p.S191= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV50890520, COSV50891913; called by muse, varscan2
- HS3ST3A1 | c.502C>T p.L168= | Silent (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- HS6ST3 | c.681C>T p.D227= | Silent (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2
- IER5L | c.1086C>G p.S362= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs757878512, COSV65262628; called by muse, mutect2, varscan2
- IER5L | c.153C>T p.R51= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs890059159; called by muse, varscan2
- IKZF1 | c.237G>A p.A79= | Silent (SNP) | VAF 18/152 reads (12%) | catalogued as rs756261862, COSV58780291; called by muse, varscan2
- IKZF4 | c.6T>C p.H2= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV56269403; called by muse, varscan2
- ING4 | c.591C>A p.T197= (on ENST00000396807 / NM_001127582.2; = p.T196= on NM_016162.4) | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, varscan2
- INTS1 | c.1539G>A p.Q513= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1373800390; called by muse, varscan2
- ISCA2 | c.276C>T p.I92= | Silent (SNP) | VAF 8/57 reads (14%) | called by muse, varscan2
- JAG2 | c.168A>G p.T56= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs754331437, COSV59306395; called by muse, varscan2
- KANSL2 | c.1212T>A p.P404= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs1311584240; called by muse, varscan2
- KANSL2 | c.1185T>C p.A395= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV63479288; called by muse, varscan2
- KATNB1 | c.681C>T p.I227= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs1441416056; called by muse, varscan2
- KCNJ9 | c.294G>C p.T98= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV63631546; called by muse, varscan2
- KCNK12 | c.873T>C p.I291= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs1275118189, COSV59945219, COSV59946737; called by muse, mutect2, varscan2
- KCNMA1 | c.2124G>A p.R708= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, varscan2
- KCNMA1 | c.351G>T p.V117= | Silent (SNP) | VAF 4/8 reads (50%) | called by muse, mutect2, varscan2
- KCNMA1 | c.271C>T p.L91= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV54226483; called by muse, varscan2
- KCNMA1 | c.213C>A p.I71= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV54226549; called by muse, varscan2
- KCTD3 | c.504C>G p.L168= | Silent (SNP) | VAF 16/169 reads (9%) | called by muse, mutect2, varscan2
- KDM2A | c.2406G>T p.T802= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV58188452; called by muse, varscan2
- KDM6A | c.129C>G p.A43= | Silent (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- KDM6A | c.2040C>T p.N680= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs1215825916, COSV65036827; called by muse, mutect2
- KIF5A | c.2596A>C p.R866= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as rs1323001440, COSV54055819; called by muse, mutect2
- KMT2A | c.300T>C p.S100= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1555138750, COSV63287064; called by muse, varscan2
- KMT2B | c.3945C>T p.D1315= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as rs1253690511, COSV55858342; called by muse, mutect2
- LCORL | c.99A>G p.R33= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV58836416; called by muse, varscan2
- LHFPL3 | c.111C>T p.N37= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV67804741; called by muse, varscan2
- LHFPL3 | c.141A>C p.I47= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV67804752; called by muse, varscan2
- LHFPL3 | c.234C>T p.G78= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV67804761; called by muse, varscan2
- LMX1B | c.255G>A p.A85= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs763085114, COSV62740182; called by mutect2, varscan2
- LPL | c.1278C>T p.F426= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs771051928, COSV60932579; called by muse, mutect2, varscan2
- LRP4 | c.2364C>T p.Y788= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV66136292; called by muse, mutect2, varscan2
- MAF | c.864G>A p.R288= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs749330861, COSV58153106; called by muse, varscan2
- MAF | c.189G>C p.P63= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, varscan2
- MAFA | c.864A>G p.Q288= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV61087495; called by muse, mutect2
- MAP7 | c.12A>G p.L4= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, varscan2
- MARK4 | c.2253G>A p.E751= | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, varscan2
- MATR3 | c.810A>G p.R270= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV63075533; called by muse, mutect2, varscan2
- MBD1 | c.1092C>T p.G364= (on ENST00000269468 / NM_001323950.1; = p.G341= on NM_015845.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs1479831959; called by muse, varscan2
- MBD5 | c.1326C>A p.P442= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs190279556, COSV68695539; called by muse, mutect2, varscan2
- MBD6 | c.153G>T p.R51= | Silent (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2
- MBD6 | c.210C>A p.V70= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, varscan2
- MCTP1 | c.273C>G p.V91= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV72405811; called by muse, varscan2
- MDGA2 | c.258G>A p.G86= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV67815654; called by muse, mutect2
- MED13L | c.120T>C p.H40= | Silent (SNP) | VAF 10/170 reads (6%) | catalogued as rs1278220741, COSV56122287; called by muse, mutect2
- MEIS2 | c.1074A>G p.A358= (on ENST00000561208 / NM_170675.5; = p.A338= on NM_002399.3) | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV54937806; called by muse, mutect2
- METTL9 | c.10C>T p.L4= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs1477287303; called by muse, mutect2
- MEX3B | c.363C>T p.A121= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs1478508710; called by muse, mutect2
- MLLT10 | c.60G>A p.E20= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs999558563, COSV56990751; called by muse, mutect2, varscan2
- MROH2B | c.4443A>C p.P1481= | Silent (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- MTSS1 | c.1164A>T p.P388= | Silent (SNP) | VAF 10/82 reads (12%) | called by muse, varscan2
- MYB | c.1152T>C p.D384= | Silent (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- MYH2 | c.3403C>A p.R1135= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV55433308; called by muse, mutect2
- MYH7B | c.5784C>T p.R1928= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- MYL6 | c.109A>C p.R37= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV52878182, COSV52879146; called by muse, varscan2
- NAV2 | c.525A>G p.G175= | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2, varscan2
- NEB | c.8529C>T p.F2843= | Silent (SNP) | VAF 34/254 reads (13%) | catalogued as COSV50807815, COSV51443776; called by muse, varscan2
- NECTIN1 | c.1188T>C p.Y396= | Silent (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2
- NFE2L1 | c.348T>C p.S116= | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, varscan2
- NKX2-1 | c.408C>T p.N136= | Silent (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
- NLGN2 | c.345C>G p.P115= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV56658574, COSV56658676; called by muse, varscan2
- NOL4 | c.1377A>C p.I459= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV52341938; called by muse, mutect2, varscan2
- NOVA1 | c.150T>C p.Y50= | Silent (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2
- NPAS3 | c.2763C>T p.G921= (on ENST00000356141 / NM_001164749.2; = p.G889= on NM_022123.3) | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs1459876588; called by muse, varscan2
- NPTN | c.393C>T p.P131= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs577243481, COSV54736552; called by muse, mutect2
- NPTN | c.171C>T p.S57= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs1052757996, COSV54736565; called by muse, mutect2, varscan2
- NR2C2 | c.33C>T p.I11= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- NR4A2 | c.1428T>G p.V476= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV59892558; called by muse, mutect2
- NR4A2 | c.153C>T p.I51= | Silent (SNP) | VAF 22/322 reads (7%) | catalogued as COSV59892427; called by muse, mutect2
- NRXN1 | c.1590C>A p.A530= | Silent (SNP) | VAF 67/252 reads (27%) | called by muse, mutect2, varscan2
- NRXN2 | c.3960G>A p.V1320= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1342517528; called by muse, varscan2
- NRXN2 | c.1080T>C p.L360= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV55455306; called by muse, varscan2
- NTRK3 | c.165C>T p.P55= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV58108948; called by muse, varscan2
- OR2A4 | c.594C>T p.V198= | Silent (SNP) | VAF 30/589 reads (5%) | called by muse, mutect2
- OR2G6 | c.135C>A p.L45= | Silent (SNP) | VAF 16/131 reads (12%) | catalogued as COSV58573593; called by muse, mutect2, varscan2
- OSR2 | c.891T>C p.C297= (on ENST00000297565 / NM_001142462.3; = p.V270A on NM_053001.3) | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV52555403; called by mutect2, varscan2
- P2RX4 | c.78C>T p.R26= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, varscan2
- PABPC4 | c.1419G>A p.P473= | Silent (SNP) | VAF 40/90 reads (44%) | catalogued as COSV63293288; called by muse, varscan2
- PATZ1 | c.1590G>A p.E530= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV56743083; called by muse, mutect2, varscan2
- PAX6 | c.87T>C p.I29= | Silent (SNP) | VAF 5/26 reads (19%) | called by muse, varscan2
- PAXIP1 | c.2496C>T p.P832= | Silent (SNP) | VAF 30/149 reads (20%) | catalogued as COSV101249392; called by muse, mutect2, varscan2
- PBX3 | c.1116A>G p.Q372= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs1280773965; called by muse, varscan2
- PBX4 | c.375T>A p.S125= | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, varscan2
- PCBP1 | c.765C>G p.T255= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs531258480, COSV57849711; called by mutect2, varscan2
- PCDH1 | c.3417A>G p.S1139= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1262259079, COSV54615130; called by muse, varscan2
- PCLO | c.14901A>G p.A4967= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV61658098; called by muse, varscan2
- PHF1 | c.624G>C p.L208= | Silent (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2
- PHF12 | c.2841G>C p.L947= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV60453001; called by muse, varscan2
- PHF21A | c.492T>C p.S164= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV57648944; called by muse, varscan2
- PKNOX2 | c.291T>C p.S97= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, varscan2
- POU3F1 | c.885C>T p.R295= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs1323985493, COSV65948430; called by muse, varscan2
- POU4F1 | c.816G>C p.A272= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs1361121694, COSV65883714; called by muse, mutect2, varscan2
- PPFIA4 | c.2265G>A p.S755= (on ENST00000447715; = p.S756= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs766066959, COSV55316443, COSV55316500; called by muse, varscan2
- PPP1CC | c.571C>A p.R191= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as rs866672821, COSV58582427; called by muse, varscan2
- PPP1R9B | c.567C>T p.F189= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1219757602; called by muse, mutect2
- PPP2R5B | c.1005T>C p.F335= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, varscan2
- PRDM12 | c.789C>T p.R263= | Silent (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- PREPL | c.1623G>T p.T541= | Silent (SNP) | VAF 32/218 reads (15%) | catalogued as COSV53218347; called by muse, mutect2, varscan2
- PRKG1 | c.78C>T p.D26= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV64821002; called by muse, varscan2
- PRPF40A | c.969G>A p.A323= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs1035377497; called by mutect2, varscan2
- PRRC2B | c.6549G>T p.V2183= | Silent (SNP) | VAF 4/43 reads (9%) | called by mutect2, varscan2
- PRRX1 | c.651C>T p.G217= | Silent (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- PSMD14 | c.357T>C p.G119= | Silent (SNP) | VAF 12/157 reads (8%) | catalogued as rs1423428612; called by muse, mutect2
- PTPRF | c.5179C>T p.L1727= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, varscan2
- PTPRT | c.1473A>G p.E491= | Silent (SNP) | VAF 7/149 reads (5%) | called by muse, mutect2
- PUM1 | c.696T>C p.D232= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2
- PURA | c.627C>T p.Y209= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs760506481, COSV58761776; called by muse, varscan2
- PURA | c.708C>T p.G236= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs1561793390, COSV58761780; called by muse, varscan2
- PXDNL | c.333T>C p.H111= | Silent (SNP) | VAF 15/112 reads (13%) | called by muse, mutect2, varscan2
- QRICH1 | c.903T>A p.I301= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV62614385; called by muse, varscan2
- RAB28 | c.6G>A p.S2= | Silent (SNP) | VAF 5/35 reads (14%) | called by muse, varscan2
- RAB6A | c.252T>A p.R84= | Silent (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2, varscan2
- RAP2A | c.87C>T p.I29= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV55354229; called by muse, mutect2
- RBFOX3 | c.369A>G p.G123= | Silent (SNP) | VAF 8/52 reads (15%) | called by muse, varscan2
- RBM14 | c.1974G>A p.A658= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs777677688, COSV59557733; called by mutect2, varscan2
- RBM27 | c.12G>A p.E4= | Silent (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- RDH10 | c.45C>G p.L15= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- RFX7 | c.417A>G p.Q139= (on ENST00000559447 / NM_001368074.1; = p.Q236= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/210 reads (5%) | catalogued as rs1465357397; called by muse, mutect2
- RIMS2 | c.4155A>T p.A1385= (on ENST00000666250 / NM_001348490.2; = p.A956= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 18/201 reads (9%) | called by muse, mutect2
- RNF11 | c.96G>A p.P32= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV54377257; called by muse, varscan2
- RUNX2 | c.114A>G p.K38= | Silent (SNP) | VAF 12/78 reads (15%) | called by muse, varscan2
- RYR1 | c.6714T>C p.Y2238= | Silent (SNP) | VAF 8/63 reads (13%) | called by muse, varscan2
- RYR2 | c.6960G>A p.V2320= | Silent (SNP) | VAF 14/201 reads (7%) | catalogued as rs1306680684, COSV100769484, COSV63703499; called by muse, mutect2
- SCN5A | c.4515G>A p.K1505= (on ENST00000333535 / NM_198056.3; = p.K1504= on NM_000335.5) | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs199473268, CM097675; called by muse, varscan2
- SCN5A | c.4464A>G p.T1488= (on ENST00000333535 / NM_198056.3; = p.T1487= on NM_000335.5) | Silent (SNP) | VAF 10/64 reads (16%) | called by muse, varscan2
- SCUBE3 | c.1989A>G p.R663= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV51454728; called by muse, mutect2, varscan2
- SEC61A2 | c.567G>A p.E189= | Silent (SNP) | VAF 14/107 reads (13%) | called by muse, varscan2
- SENP3 | c.1626T>C p.H542= | Silent (SNP) | VAF 12/64 reads (19%) | called by muse, varscan2
- SETD5 | c.219T>C p.P73= | Silent (SNP) | VAF 20/200 reads (10%) | catalogued as COSV56707045; called by muse, varscan2
- SFMBT1 | c.1092G>A p.Q364= | Silent (SNP) | VAF 5/22 reads (23%) | called by mutect2, varscan2
- SFRP1 | c.363C>T p.C121= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1411640698; called by muse, varscan2
- SFRP2 | c.162A>G p.E54= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV56836682; called by muse, varscan2
- SHISA6 | c.543C>T p.T181= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs929771196, COSV58645204; called by muse, mutect2
- SIX3 | c.288T>C p.C96= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV53227290; called by muse, varscan2
- SKIDA1 | c.84C>T p.A28= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, varscan2
- SLC35E3 | c.273T>C p.T91= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV57492711; called by muse, varscan2
- SLC43A2 | c.753G>A p.L251= | Silent (SNP) | VAF 5/19 reads (26%) | called by muse, varscan2
- SLC4A3 | c.186C>T p.P62= | Silent (SNP) | VAF 6/16 reads (38%) | called by muse, varscan2
- SLC6A9 | c.375C>T p.R125= (on ENST00000360584 / NM_201649.4; = p.R71= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV62209789; called by muse, varscan2
- SLITRK1 | c.1812G>A p.T604= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs761500540, COSV65674050; called by muse, varscan2
- SMAD6 | c.1059C>T p.A353= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs755030867; called by mutect2, varscan2
- SMARCC2 | c.3507A>G p.Q1169= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV53237190; called by muse, mutect2, varscan2
- SMG1 | c.63T>C p.Y21= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs752058454; called by muse, varscan2
- SNTB2 | c.450T>G p.A150= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs1197353929, COSV60352376; called by mutect2, varscan2
- SOX1 | c.316C>A p.R106= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV58378205; called by muse, varscan2
- SOX10 | c.225C>G p.A75= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV61005474; called by muse, varscan2
- SOX14 | c.90C>T p.N30= | Silent (SNP) | VAF 6/56 reads (11%) | called by muse, varscan2
- SOX14 | c.588T>G p.P196= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV60163011; called by muse, varscan2
- SOX14 | c.645C>T p.P215= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV60163019; called by muse, mutect2, varscan2
- SP1 | c.2274C>T p.G758= (on ENST00000327443 / NM_138473.3; = p.G751= on NM_003109.1) | Silent (SNP) | VAF 8/43 reads (19%) | called by mutect2, varscan2
- SPCS3 | c.114G>A p.P38= | Silent (SNP) | VAF 6/53 reads (11%) | called by muse, varscan2
- SPTBN2 | c.549T>G p.L183= | Silent (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- SRCAP | c.3645G>A p.K1215= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, varscan2
- SRSF10 | c.750A>G p.R250= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV58360733; called by muse, varscan2
- ST8SIA2 | c.39C>T p.L13= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs770900422; called by mutect2, varscan2
- SYN2 | c.1683G>A p.E561= | Silent (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2
- SYNGAP1 | c.1878T>C p.I626= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as rs1354630489; ClinVar: likely benign; called by muse, varscan2
- SYT12 | c.96G>T p.L32= | Silent (SNP) | VAF 9/38 reads (24%) | called by muse, varscan2
- TAF3 | c.18C>T p.S6= | Silent (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- TAOK1 | c.2905C>T p.L969= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV55593034; called by muse, varscan2
- TBC1D14 | c.1380A>G p.E460= | Silent (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- TBX15 | c.87A>G p.K29= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV52872184; called by muse, varscan2
- TCF7 | c.1098C>T p.C366= (on ENST00000395029; = p.C251= on NM_201634.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- TENM2 | c.2292G>T p.A764= (on ENST00000518659 / NM_001122679.2; = p.A532= on NM_001080428.3) | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV69122442; called by muse, mutect2, varscan2
- TENM3 | c.7578C>G p.A2526= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV69299051; called by muse, mutect2, varscan2
- TERT | c.2214G>A p.T738= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs200858212; ClinVar: likely benign; called by mutect2, varscan2
- TM9SF4 | c.1143A>T p.T381= | Silent (SNP) | VAF 9/48 reads (19%) | called by muse, varscan2
- TMEM164 | c.99C>G p.L33= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV55810399; called by muse, varscan2
- TMEM178A | c.162C>T p.D54= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs1196821763, COSV56142368; called by muse, varscan2
- TMEM178B | c.270C>T p.A90= | Silent (SNP) | VAF 4/17 reads (24%) | called by muse, varscan2
- TMEM266 | c.270G>A p.V90= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV101189641; called by muse, varscan2
- TMEM63B | c.1875C>T p.A625= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as rs1194072112, COSV52479973; called by mutect2, varscan2
- TNR | c.1101C>T p.L367= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV54869502; called by muse, varscan2
- TNRC6A | c.4065T>C p.L1355= | Silent (SNP) | VAF 9/169 reads (5%) | called by muse, mutect2
- TNRC6A | c.4734C>T p.N1578= | Silent (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
- TNRC6A | c.5046C>T p.N1682= | Silent (SNP) | VAF 14/130 reads (11%) | catalogued as rs147946438; called by muse, mutect2
- TRIB2 | c.24C>T p.P8= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV50224260; called by muse, mutect2, varscan2
- TRPC4 | c.1206C>G p.V402= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, varscan2
- TUBB | c.1266T>C p.Y422= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- TUBB3 | c.48C>A p.I16= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, varscan2
- TUBG1 | c.741C>A p.G247= | Silent (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- UBE2N | c.126T>C p.P42= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as rs757272746, COSV58866713; called by muse, varscan2
- UBE2O | c.1053G>A p.E351= | Silent (SNP) | VAF 5/28 reads (18%) | called by muse, varscan2
- UBR4 | c.8529G>C p.L2843= | Silent (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- UNC79 | c.321C>T p.P107= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as rs1372490934, COSV56393927; called by muse, varscan2
- UNC80 | c.57C>T p.P19= | Silent (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- UNCX | c.114G>T p.G38= | Silent (SNP) | VAF 7/18 reads (39%) | called by muse, varscan2
- USP21 | c.1143T>C p.C381= | Silent (SNP) | VAF 14/86 reads (16%) | called by muse, varscan2
- USP7 | c.225G>C p.V75= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV61212825; called by muse, mutect2, varscan2
- VCL | c.2532G>T p.P844= | Silent (SNP) | VAF 11/177 reads (6%) | catalogued as COSV53008394; called by muse, mutect2
- VIRMA | c.3489C>T p.R1163= | Silent (SNP) | VAF 18/324 reads (6%) | catalogued as COSV52581353; called by muse, mutect2
- WDR20 | c.591G>A p.E197= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV54470123; called by muse, varscan2
- WLS | c.786C>T p.P262= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs748998121; called by muse, varscan2
- WNK1 | c.6594C>T p.F2198= (on ENST00000315939 / NM_018979.4; = p.F1950= on NM_014823.3) | Silent (SNP) | VAF 13/304 reads (4%) | catalogued as rs1317693605; called by muse, mutect2
- XKR6 | c.45T>C p.A15= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs770211171, COSV52008917; called by muse, varscan2
- YBX1 | c.414T>C p.Y138= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1414866593; called by muse, mutect2
- YPEL3 | c.48T>C p.D16= (on ENST00000398838 / NM_001145524.2; = p.D54= on NM_031477.5) | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs748659567; called by muse, varscan2
- YTHDF3 | c.972A>G p.Q324= | Silent (SNP) | VAF 19/168 reads (11%) | catalogued as rs1171980454, COSV72773175; called by muse, mutect2, varscan2
- YY1 | c.117A>G p.T39= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1240639847, COSV51763309; called by muse, varscan2
- ZBTB18 | c.603A>C p.A201= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV62396182; called by muse, mutect2, varscan2
- ZBTB18 | c.834T>G p.A278= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV62396192; called by muse, varscan2
- ZCCHC2 | c.336G>T p.L112= | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2
- ZFHX3 | c.8829G>A p.R2943= | Silent (SNP) | VAF 5/56 reads (9%) | called by muse, varscan2
- ZFHX4 | c.18C>T p.S6= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV99266884; called by muse, mutect2
- ZFP82 | c.6C>G p.A2= | Silent (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- ZIC5 | c.1539T>C p.R513= | Silent (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2
- ZNF281 | c.1035T>C p.Y345= | Silent (SNP) | VAF 11/199 reads (6%) | catalogued as COSV54167550; called by muse, mutect2
- ZNF282 | c.52C>T p.L18= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs1426928439, COSV50481660; called by muse, varscan2
- ZNF418 | c.63C>T p.L21= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as rs1315837116, COSV101268927; called by muse, mutect2, varscan2
- ZNF592 | c.2475T>C p.V825= | Silent (SNP) | VAF 12/92 reads (13%) | called by muse, varscan2
- ZNF608 | c.438A>T p.A146= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV60436057; called by muse, varscan2
- ZNF740 | c.18C>T p.L6= | Silent (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- ZSWIM5 | c.3168G>A p.E1056= | Silent (SNP) | VAF 7/76 reads (9%) | called by muse, varscan2
- AC103993.1 | n.117G>C | RNA (SNP) | VAF 28/214 reads (13%) | catalogued as rs1221912945; called by muse, varscan2
- AL353804.6 | chrX:73827225 T>G | 3'Flank (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- BRD2 | c.333+265T>C | Intron (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- BRD2 | c.333+267G>T | Intron (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2
- BRD7 | c.-16C>T | 5'UTR (SNP) | VAF 4/15 reads (27%) | catalogued as rs1243039219; called by muse, mutect2
- BRD7 | c.-18A>T | 5'UTR (SNP) | VAF 4/15 reads (27%) | catalogued as rs1567297326; called by muse, mutect2
- C2orf83 | n.371del | RNA (DEL) | VAF 18/85 reads (21%) | called by mutect2, pindel, varscan2
- CA10 | c.-19T>C | 5'UTR (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
- CASP2 | c.967+177G>A | Intron (SNP) | VAF 11/99 reads (11%) | catalogued as rs1287827257; called by muse, mutect2, varscan2
- CCNYL2 | n.624-2639G>T | Intron (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- CCNYL2 | n.624-2640G>C | Intron (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- CHEK2 | c.721+116G>A | Intron (SNP) | VAF 12/70 reads (17%) | catalogued as rs1196006038; called by muse, mutect2
- CHKA | c.463-9C>T | Intron (SNP) | VAF 8/73 reads (11%) | catalogued as rs1205634989; called by muse, varscan2
- CNFN | c.-2-465A>C | Intron (SNP) | VAF 6/43 reads (14%) | called by muse, varscan2
- CSN1S2AP | n.356G>A | RNA (SNP) | VAF 27/253 reads (11%) | called by muse, mutect2, varscan2
- CSNK1D | c.*12A>T | 3'UTR (SNP) | VAF 16/104 reads (15%) | called by muse, varscan2
- CTBP2 | c.59-2122G>T | Intron (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- DDX39B | c.735+48C>T | Intron (SNP) | VAF 6/34 reads (18%) | called by muse, varscan2
- EGFEM1P | n.515C>T | RNA (SNP) | VAF 5/49 reads (10%) | catalogued as rs1338196946; called by muse, mutect2
- ELF2 | c.239-10642C>T | Intron (SNP) | VAF 12/42 reads (29%) | catalogued as rs746872105; called by muse, varscan2
- EPHB1 | c.805+25963G>T | Intron (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- GRHL1 | c.-6G>A | 5'UTR (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- GRIN1 | c.*243G>A | 3'UTR (SNP) | VAF 5/35 reads (14%) | catalogued as rs933234320; called by muse, mutect2, varscan2
- HDAC5 | c.-27C>T | 5'UTR (SNP) | VAF 5/33 reads (15%) | called by muse, varscan2
- HM13 | c.1035-925C>T | Intron (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2
- HMGXB4 | c.-30_-26dup | 5'UTR (INS) | VAF 9/64 reads (14%) | called by pindel, varscan2
- HOXA11 | c.-1A>G | 5'UTR (SNP) | VAF 12/156 reads (8%) | catalogued as COSV99136147; called by muse, mutect2
- HOXC9 | c.-7C>T | 5'UTR (SNP) | VAF 18/89 reads (20%) | called by muse, varscan2
- INTS10 | c.1977-2463A>G | Intron (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- ISG15 | c.-27G>T | 5'UTR (SNP) | VAF 5/33 reads (15%) | called by mutect2, varscan2
- JADE1 | c.-14T>C | 5'UTR (SNP) | VAF 9/41 reads (22%) | called by muse, varscan2
- JMJD6 | c.941+480A>C | Intron (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2
- KCNC1 | chr11:17779556 G>C | 3'Flank (SNP) | VAF 6/23 reads (26%) | catalogued as COSV56397372; called by muse, mutect2, varscan2
- KCNC1 | chr11:17781660 T>C | 3'Flank (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- KCNIP4 | c.61+251102G>T | Intron (SNP) | VAF 30/177 reads (17%) | catalogued as COSV66178073; called by muse, varscan2
- KHDRBS3 | c.88+927G>C | Intron (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2, varscan2
- KRT6A | c.-38C>A | 5'UTR (SNP) | VAF 28/112 reads (25%) | catalogued as rs1280105759; called by muse, varscan2
- LINC02649 | n.468C>G | RNA (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- LINC02871 | n.1028G>A | RNA (SNP) | VAF 10/96 reads (10%) | catalogued as rs1240173108; called by muse, mutect2, varscan2
- MARCHF8 | c.242+883G>T | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100165758; called by muse, mutect2, varscan2
- MARCKS | c.-40C>T | 5'UTR (SNP) | VAF 4/42 reads (10%) | called by mutect2, varscan2
- MBD5 | c.2845+621A>C | Intron (SNP) | VAF 8/78 reads (10%) | catalogued as COSV101290117; called by muse, varscan2
- MEGF11 | c.2711-2912C>T | Intron (SNP) | VAF 8/32 reads (25%) | catalogued as rs1235240511; called by muse, mutect2, varscan2
- MEGF11 | c.2711-2913C>A | Intron (SNP) | VAF 6/30 reads (20%) | called by mutect2, varscan2
- MIR212 | n.66C>T | RNA (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- MYO9A | c.5142+659G>C | Intron (SNP) | VAF 5/46 reads (11%) | catalogued as rs1380668478; called by muse, varscan2
- NF1 | c.4111-40T>C | Intron (SNP) | VAF 12/224 reads (5%) | called by muse, mutect2
- NKX2-1 | c.-249C>T | 5'UTR (SNP) | VAF 6/48 reads (13%) | catalogued as rs911284825; called by muse, mutect2, varscan2
- NPAS3 | chr14:32939308 A>T | 5'Flank (SNP) | VAF 7/35 reads (20%) | called by muse, varscan2
- OR2L1P | n.485C>G | RNA (SNP) | VAF 13/150 reads (9%) | called by muse, mutect2
- P4HTM | c.724+88del | Intron (DEL) | VAF 9/54 reads (17%) | called by mutect2, pindel, varscan2
- PCBP2 | c.1061+3164C>T | Intron (SNP) | VAF 6/29 reads (21%) | catalogued as COSV63730215; called by muse, varscan2
- PCBP2 | c.1061+3200C>T | Intron (SNP) | VAF 6/42 reads (14%) | catalogued as rs1221331222; called by muse, varscan2
- PCBP3 | c.675+12T>C | Intron (SNP) | VAF 9/40 reads (23%) | called by muse, varscan2
- PCDH9 | c.3036+36A>C | Intron (SNP) | VAF 6/36 reads (17%) | called by mutect2, varscan2
- PPIP5K1 | c.3248-1513G>A | Intron (SNP) | VAF 11/77 reads (14%) | catalogued as rs753616898; called by muse, mutect2, varscan2
- PPP2R2B | c.-59A>T | 5'UTR (SNP) | VAF 11/50 reads (22%) | catalogued as COSV60768468; called by muse, varscan2
- PRRC2C | c.8199+935T>A | Intron (SNP) | VAF 14/102 reads (14%) | called by muse, varscan2
- RABGAP1L | c.2212-11392G>A | Intron (SNP) | VAF 10/79 reads (13%) | catalogued as COSV52301842; called by muse, varscan2
- RBFOX3 | c.756-21T>C | Intron (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2, varscan2
- SATL1 | c.-446C>T | 5'UTR (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- SCUBE1 | c.727+2724A>C | Intron (SNP) | VAF 8/70 reads (11%) | called by muse, varscan2
- SETD5 | c.178-157A>G | Intron (SNP) | VAF 12/194 reads (6%) | catalogued as COSV56712180; called by muse, mutect2
- SIX4 | c.-196A>G | 5'UTR (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- SLC24A1 | c.2054-1459C>T | Intron (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- SUSD4 | c.725-5668A>G | Intron (SNP) | VAF 17/266 reads (6%) | catalogued as COSV59549841; called by muse, mutect2
- SYT7 | c.215+5280G>A | Intron (SNP) | VAF 6/12 reads (50%) | catalogued as rs540013742; called by muse, varscan2
- TBC1D3P2 | n.827C>A | RNA (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- TENT5A | c.-38+26C>T | Intron (SNP) | VAF 6/18 reads (33%) | catalogued as rs1389702388; called by muse, mutect2, varscan2
- TTBK1 | c.1986+6355G>T | Intron (SNP) | VAF 9/38 reads (24%) | catalogued as COSV52488021; called by muse, varscan2
- TTBK1 | c.1986+6394T>C | Intron (SNP) | VAF 10/30 reads (33%) | catalogued as COSV52492471; called by muse, varscan2
- TTN | c.34265-5670C>T | Intron (SNP) | VAF 24/126 reads (19%) | catalogued as COSV100596006; called by muse, mutect2, varscan2
- TTN | c.10361-4252C>A | Intron (SNP) | VAF 14/120 reads (12%) | called by mutect2, varscan2
- UBAP2L | c.2902+1467G>C | Intron (SNP) | VAF 12/190 reads (6%) | catalogued as COSV55167640; called by muse, mutect2
- UNC79 | chr14:93431017 A>T | 5'Flank (SNP) | VAF 6/34 reads (18%) | called by muse, varscan2
- XIST | n.11400C>A | RNA (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- YTHDF3 | c.-10G>A | 5'UTR (SNP) | VAF 7/65 reads (11%) | called by muse, varscan2
- ZEB2 | c.-87G>A | 5'UTR (SNP) | VAF 6/41 reads (15%) | catalogued as rs1205265082; called by muse, varscan2
- ZFR | c.-61C>T | 5'UTR (SNP) | VAF 6/63 reads (10%) | catalogued as rs1354875961; called by muse, varscan2
- ZNF462 | c.6013-21A>C | Intron (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- ZNF462 | c.6013-19A>G | Intron (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- ZNF778 | c.*4342A>C | 3'UTR (SNP) | VAF 8/114 reads (7%) | catalogued as rs1226788008; called by muse, mutect2
